Somatic mutation profile of tumor specimen TCGA-ZS-A9CG-01A (aliquot TCGA-ZS-A9CG-01A-11D-A36X-10) from TCGA case TCGA-ZS-A9CG, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 55.0 years (20,100 days).
Specimen TCGA-ZS-A9CG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 410148ed-b66b-482c-adc7-f2fb5d179814.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZS-A9CG-10A (Blood Derived Normal), aliquot TCGA-ZS-A9CG-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d9da441-fd67-42ad-8179-7331a60b9094

The open-access MAF lists 88 somatic variants for this specimen: 68 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 18, Splice Site 3, Frame Shift Ins 2, RNA 2, Frame Shift Del 2, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 105/150 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.590T>A p.M197K | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as COSV99713043; called by muse, mutect2, varscan2
- ABCF1 | c.2437G>A p.E813K (on ENST00000326195 / NM_001025091.2; = p.E775K on NM_001090.3) | Missense Mutation (SNP) | VAF 81/212 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as COSV100400839; called by muse, mutect2, varscan2
- ADGRL4 | c.1882G>T p.G628C | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100875948, COSV66064393; called by muse, mutect2, varscan2
- ANKRD24 | c.1570G>T p.A524S | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV99517491; called by muse, mutect2, varscan2
- APOBEC3G | c.200A>T p.E67V | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV101349077; called by muse, mutect2, varscan2
- ATAD2 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 40/222 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99784689; called by muse, mutect2, varscan2
- BAP1 | c.1616T>A p.L539Q | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV99963950; called by muse, mutect2, varscan2
- BMF | c.217C>A p.L73I | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); catalogued as COSV99590430; called by muse, mutect2, varscan2
- BRINP3 | c.1804G>T p.D602Y | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV100818744, COSV66532828; called by muse, mutect2, varscan2
- BRSK1 | c.1145T>C p.V382A | Missense Mutation (SNP) | VAF 88/259 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV100474087; called by muse, mutect2, varscan2
- CASP3 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100394978; called by muse, mutect2, varscan2
- CCDC60 | c.308T>A p.I103N | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.295); catalogued as COSV100555086; called by muse, mutect2, varscan2
- CCKAR | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.967); catalogued as rs140102483; called by muse, mutect2, varscan2
- CELF2 | c.949A>G p.S317G (on ENST00000416382 / NM_001025077.3; = p.S324G on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100257558; called by muse, mutect2, varscan2
- CEMIP2 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as rs764831667, COSV100987379; called by muse, mutect2, varscan2
- CLVS1 | c.221C>A p.A74D | Missense Mutation (SNP) | VAF 166/240 reads (69%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as COSV100369981, COSV57970073; called by muse, varscan2
- DCDC2 | c.662G>T p.S221I | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV101016298, COSV65831541; called by muse, mutect2, varscan2
- DDX43 | c.1306C>A p.R436S | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64813722; called by muse, mutect2, varscan2
- DGKI | c.2492T>C p.L831P | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99934446; called by muse, mutect2, varscan2
- DYNC2I1 | c.2057C>A p.P686H | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101337673; called by muse, mutect2, varscan2
- FILIP1 | c.3325C>T p.L1109F | Missense Mutation (SNP) | VAF 79/214 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.753); catalogued as rs1488362044, COSV99384812; called by muse, mutect2, varscan2
- FREM2 | c.2944A>G p.T982A | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs1157011161, COSV99748738; called by muse, mutect2, varscan2
- HECTD1 | c.2683A>T p.N895Y | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as COSV101125715; called by muse, mutect2, varscan2
- HSPG2 | c.465T>A p.N155K | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV101012944; called by muse, mutect2, varscan2
- IKBKE | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1281179215, COSV100898233; called by muse, mutect2, varscan2
- JADE2 | c.154G>T p.V52F | Missense Mutation (SNP) | VAF 113/292 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99253228; called by muse, mutect2
- KIAA1549 | c.1181A>G p.H394R | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99650779; called by muse, mutect2, varscan2
- LAMA1 | c.4897C>T p.L1633F | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.691); catalogued as COSV101056382, COSV101058261; called by muse, mutect2, varscan2
- LAMA3 | c.4264G>C p.G1422R | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV58062343; called by muse, mutect2, varscan2
- LDHAL6A | c.967C>T p.L323F | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99323936; called by muse, mutect2, varscan2
- LRRK1 | c.3803C>T p.A1268V | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV99439956; called by muse, mutect2, varscan2
- MCM4 | c.1435-1G>A p.X479_splice | Splice Site (SNP) | VAF 12/246 reads (5%) | catalogued as COSV100031537; called by muse, mutect2
- MEX3D | c.697G>A p.V233M | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66312013, COSV66312123; called by muse, mutect2, varscan2
- MMUT | c.1952T>A p.F651Y | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99222335; called by muse, mutect2, varscan2
- NAA60 | c.657C>A p.S219R | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV100692802; called by muse, mutect2, varscan2
- NDUFS1 | c.1697T>G p.I566S | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV99260931; called by muse, mutect2, varscan2
- NECAP1 | c.779G>A p.S260N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.4); catalogued as COSV100331581; called by muse, mutect2, varscan2
- NFKB1 | c.2135T>G p.V712G (on ENST00000394820 / NM_001382627.1; = p.V713G on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99897170; called by muse, mutect2, varscan2
- NID2 | c.82G>C p.A28P | Missense Mutation (SNP) | VAF 77/211 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as COSV99356534; called by muse, mutect2, varscan2
- NUGGC | c.1807A>G p.I603V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs746082643, COSV100429249; called by muse, mutect2, varscan2
- NYAP2 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99796613; called by muse, mutect2, varscan2
- PCDHB3 | c.190dup p.A64Gfs*20 | Frame Shift Ins (INS) | VAF 51/254 reads (20%) | catalogued as rs1554272095; called by mutect2, pindel, varscan2
- PIGU | c.1080C>G p.C360W | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99466426; called by muse, mutect2, varscan2
- PLEKHA5 | c.2264G>A p.R755H | Missense Mutation (SNP) | VAF 147/400 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs142164989; called by muse, mutect2, varscan2
- PNKP | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as rs1284293244, COSV99681747; called by muse, mutect2, varscan2
- PPP2R3B | c.865A>G p.S289G | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.616); catalogued as COSV101065532; called by muse, varscan2
- PRPF6 | c.33G>T p.M11I | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs796657288, COSV99411983; called by muse, mutect2, varscan2
- PSMC2 | c.1105A>T p.R369* | Nonsense Mutation (SNP) | VAF 24/96 reads (25%) | catalogued as COSV99485299; called by muse, mutect2, varscan2
- PTGIS | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as rs745642215, COSV54836304; called by muse, mutect2, varscan2
- PTPRN2 | c.1472C>A p.A491D | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.222); catalogued as COSV101234422; called by muse, mutect2, varscan2
- RASGRP4 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV53097089; called by muse, mutect2, varscan2
- ROBO2 | c.388+2T>C p.X130_splice | Splice Site (SNP) | VAF 55/83 reads (66%) | catalogued as COSV100166726; called by muse, mutect2, varscan2
- SEMA3D | c.1382A>T p.D461V | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1418234177, COSV99406634; called by muse, mutect2, varscan2
- SESTD1 | c.825A>T p.E275D | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100090500; called by muse, mutect2, varscan2
- SHROOM3 | c.5297T>C p.M1766T | Missense Mutation (SNP) | VAF 77/203 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV99934320; called by muse, mutect2, varscan2
- SLAMF8 | c.485A>G p.Y162C | Missense Mutation (SNP) | VAF 89/182 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1267669878, COSV99222921; called by muse, mutect2, varscan2
- SMO | c.2272T>A p.W758R | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV99976656; called by muse, mutect2, varscan2
- SPTA1 | c.708G>T p.Q236H | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.389); catalogued as COSV63755426; called by muse, mutect2, varscan2
- THOP1 | c.1824G>C p.Q608H | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100310579; called by muse, mutect2, varscan2
- UBASH3B | c.1452T>G p.G484= | Splice Region (SNP) | VAF 48/116 reads (41%) | catalogued as COSV99417738; called by muse, mutect2, varscan2
- WDR36 | c.1397G>C p.G466A | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV101540800; called by muse, mutect2, varscan2
- YLPM1 | c.3439C>T p.P1147S | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.022); catalogued as COSV99459675; called by muse, mutect2, varscan2
- ACCSL | c.798_804del p.F266Lfs*15 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | called by mutect2, pindel, varscan2
- ALB | c.482+5_482+8del p.X161_splice | Splice Site (DEL) | VAF 24/94 reads (26%) | called by pindel, varscan2
- CBL | c.2227_2233dup p.T745Ifs*10 | Frame Shift Ins (INS) | VAF 30/98 reads (31%) | called by mutect2, varscan2
- CHUK | c.438del p.K146Nfs*5 | Frame Shift Del (DEL) | VAF 42/105 reads (40%) | called by mutect2, pindel, varscan2
- SYNRG | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ACSF2 | c.516C>T p.C172= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV99366191; called by muse, mutect2, varscan2
- ADCY1 | c.2937C>T p.I979= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as COSV99811983; called by muse, mutect2, varscan2
- CNTN4 | c.2973G>A p.K991= | Silent (SNP) | VAF 8/209 reads (4%) | catalogued as COSV100639248, COSV104422311; called by muse, mutect2
- COL5A3 | c.2775A>T p.T925= | Silent (SNP) | VAF 22/170 reads (13%) | catalogued as COSV99318891; called by muse, mutect2, varscan2
- CYP2D6 | c.378C>G p.P126= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV100637307; called by muse, mutect2, varscan2
- DBI | c.6T>G p.S2= | Silent (SNP) | VAF 15/133 reads (11%) | catalogued as COSV100275876; called by muse, mutect2
- GPR25 | c.241C>T p.L81= | Silent (SNP) | VAF 47/94 reads (50%) | catalogued as COSV100421735; called by muse, mutect2, varscan2
- POU4F3 | c.618G>A p.A206= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as rs1490367253, COSV100047236, COSV57942161; called by muse, mutect2, varscan2
- PRDM1 | c.729C>T p.V243= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV100958768; called by muse, mutect2, varscan2
- RHOBTB2 | c.1371C>G p.V457= | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as COSV99310920, COSV99310968; called by muse, mutect2, varscan2
- RHOT2 | c.1632C>T p.R544= | Silent (SNP) | VAF 35/106 reads (33%) | catalogued as COSV99558731; called by muse, mutect2, varscan2
- RPH3AL | c.915A>T p.A305= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100046962; called by muse, mutect2, varscan2
- TACC2 | c.5739G>C p.S1913= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100552338, COSV57766647; called by muse, mutect2, varscan2
- TACC2 | c.5982T>C p.S1994= (on ENST00000334433; = p.S72= on NM_006997.4) | Silent (SNP) | VAF 55/148 reads (37%) | catalogued as COSV99587071; called by muse, mutect2, varscan2
- TRPC7 | c.465C>T p.D155= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as rs778432814, COSV100725483; called by muse, mutect2, varscan2
- UNC13C | c.786A>G p.E262= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV99517101; called by muse, mutect2, varscan2
- WNK2 | c.6556C>T p.L2186= (on ENST00000297954 / NM_001282394.1; = p.L2149= on NM_006648.3) | Silent (SNP) | VAF 34/244 reads (14%) | catalogued as COSV99942297; called by muse, mutect2, varscan2
- ZNF18 | c.924C>A p.L308= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV100503108; called by muse, mutect2, varscan2
- MIR363 | n.7C>A | RNA (SNP) | VAF 309/368 reads (84%) | called by muse, mutect2, varscan2
- ZNF658B | n.1743G>A | RNA (SNP) | VAF 4/16 reads (25%) | called by mutect2, varscan2
